Gene-level copy-number profile of tumor specimen HTMCP-03-06-02125-01B from CGCI case HTMCP-03-06-02125, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 26.9 years (9,843 days).
Specimen HTMCP-03-06-02125-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6341383-83dc-4065-9dd0-f31691aa484c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02125-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,276 have no estimate.
https://portal.gdc.cancer.gov/files/5fe1b11d-7b5e-4d74-9049-c6fd4b752bfd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 8,247; copy number 2: 41,622; copy number 3: 8,240; copy number 4: 39; copy number 5: 73; copy number 6: 17; copy number 8: 58; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,676,851–149,747,818, 2 genes (within-gene range 0–2): AC243772.3, RNU1-68P.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr7:67,278,714–67,286,664, 1 gene: SPDYE21.
- chr7:67,297,653–67,297,754, 1 gene (within-gene range 0–2): Y_RNA.
- chr7:102,637,049–102,690,469, 4 genes (within-gene range 0–3): AC105052.3, SPDYE2B, POLR2J2, RASA4DP.
- chr7:149,714,781–150,343,346, 20 genes (within-gene range 0–1): KRBA1, ZNF467, SSPOP, ZNF862, AC004877.2, AC004877.1, ATP6V0E2-AS1, ATP6V0E2, AC093458.1, AC093458.2, AC092681.3, AC092681.1, AC092681.2, AC092666.1, AC092666.2, ACTR3C, ZBED6CL, LRRC61, AC005586.1, RARRES2.
- chr8:12,362,019–12,388,296, 3 genes: FAM66A, AC087203.1, AC087203.2.
- chr8:12,628,476–12,629,256, 1 gene: RPS3AP35.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:9,799,423–9,803,784, 1 gene (within-gene range 0–1): AL513422.1.
- chr12:132,031,224–132,031,359, 1 gene (within-gene range 0–1): SNORA49.
- chr16:31,975,803–32,003,728, 1 gene: AC142381.3.
- chr22:18,422,244–18,500,594, 1 gene (within-gene range 0–2): FAM230A.
- chr22:18,501,794–18,530,573, 5 genes: FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 149 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:88,051,944–88,168,729, 5 genes, copy number 5: CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38.
- chr3:90,202,316–90,261,708, 2 genes, copy number 5: PROS2P, HSPE1P19.
- chr7:38,239,580–38,249,572, 1 gene, copy number 6: TRGC2.
- chr7:38,256,337–38,340,998, 15 genes, copy number 6: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr9:34,049,966–34,050,244, 1 gene, copy number 5: RN7SKP114.
- chr9:64,817,870–64,836,341, 1 gene, copy number 6: AL359955.1.
- chr14:22,086,407–22,497,718, 57 genes, copy number 8: TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41.
- chr14:22,547,506–22,552,156, 1 gene, copy number 8: TRAC.
- chr15:32,250,302–32,367,784, 4 genes, copy number 5: AC139426.3, RNU6-18P, AC139426.1, AC139426.2.
- chr21:8,680,538–8,680,934, 1 gene, copy number 20: CR381572.2.
- chr22:16,725,072–16,821,699, 3 genes, copy number 5: AC005301.2, LINC01665, XKR3.
- chr22:20,198,729–21,142,371, 58 genes, copy number 5: AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, BCRP2, AP000550.1, POM121L7P, E2F6P2.

Autosomal genes at a single copy (total copy number 1): 7,713. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
